Somatic mutation profile of tumor specimen 0DU4VF from CCDI case PBCJCR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Pancreatic duct; Age at diagnosis: 4.6 years (1,671 days).
Specimen 0DU4VF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13302251-4480-4d92-9b50-a2c9bcefd88e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU4V1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a4d4057-6be5-43c6-9759-82bd791c4d0f

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Nonsense Mutation 2, Frame Shift Ins 1, Silent 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 804/2160 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 68/2081 reads (3%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- ERI2 | c.1738A>T p.T580S | Missense Mutation (SNP) | VAF 757/2021 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- INO80D | c.1540dup p.M514Nfs*3 | Frame Shift Ins (INS) | VAF 765/1852 reads (41%) | called by mutect2, varscan2
- INTS11 | c.1735C>T p.Q579* | Nonsense Mutation (SNP) | VAF 442/1207 reads (37%) | called by muse, mutect2, varscan2
- PNLIPRP1 | c.101G>A p.W34* | Nonsense Mutation (SNP) | VAF 765/2084 reads (37%) | called by mutect2, varscan2
- SERPINA12 | c.202C>A p.P68T | Missense Mutation (SNP) | VAF 439/1208 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- NPDC1 | c.456G>A p.T152= | Silent (SNP) | VAF 576/1508 reads (38%) | catalogued as rs368058776; called by mutect2, varscan2
- PAXBP1 | c.-42C>T | 5'UTR (SNP) | VAF 372/1150 reads (32%) | called by muse, mutect2, varscan2
- PCSK1N | c.*72G>A | 3'UTR (SNP) | VAF 502/1282 reads (39%) | called by muse, mutect2, varscan2
